Somatic mutation profile of tumor specimen TCGA-AA-3811-01A (aliquot TCGA-AA-3811-01A-01W-0995-10) from TCGA case TCGA-AA-3811, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with neuroendocrine differentiation; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 84.6 years (30,893 days).
Specimen TCGA-AA-3811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f91974b-8271-4c2f-8ee1-e01faf7405c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3811-10A (Blood Derived Normal), aliquot TCGA-AA-3811-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80784ace-c178-4070-9585-bdd840f6c6bb

The open-access MAF lists 2,059 somatic variants for this specimen: 1,549 protein-altering or splice-affecting, 466 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,200, Silent 466, Frame Shift Del 201, Nonsense Mutation 58, Splice Site 32, Frame Shift Ins 31, Intron 21, In Frame Del 14, Splice Region 11, RNA 9, 3'Flank 5, 3'UTR 5.

Variants (750 of 2,059; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 71/267 reads (27%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 26/224 reads (12%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CPT1A | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs397515544, CM103685, COSV99680475; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 60/85 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 147/171 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- EGFR | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 223/264 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477025000, COSV51779162, COSV51807036; called by muse, mutect2, varscan2
- HDAC4 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064797002, COSV61866558; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 80/254 reads (31%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KMT2A | c.6478C>T p.R2160* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as rs1555045816, COSV100627683; ClinVar: pathogenic; called by muse, mutect2
- LAMA2 | c.3829C>T p.R1277* | Nonsense Mutation (SNP) | VAF 17/26 reads (65%) | catalogued as rs1554269891, COSV70354446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMAA | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 25/344 reads (7%) | catalogued as rs1029096863, CM113629, COSV99849569; ClinVar: pathogenic; called by muse, mutect2
- NEK8 | c.2076dup p.*693Lfs*86 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | catalogued as rs755820155; ClinVar: pathogenic; called by mutect2, varscan2
- PGR | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 94/329 reads (29%) | hotspot (GDC flag); catalogued as rs776604342, COSV99677260; called by muse, mutect2, varscan2
- RPE65 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61751281, CM983757; ClinVar: pathogenic; called by muse, mutect2
- SLC12A6 | c.550del p.Q184Kfs*19 (on ENST00000354181 / NM_001365088.1; = p.Q133Kfs*19 on NM_005135.2) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1057517109; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 272/387 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAR | c.125dup p.T44Hfs*3 | Frame Shift Ins (INS) | VAF 30/62 reads (48%) | catalogued as rs750549499; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 61/103 reads (59%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100228408; called by muse, mutect2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- ABCA1 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV101036379; called by muse, mutect2
- ABCB4 | c.1958T>A p.M653K | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99709543; called by muse, mutect2
- ABCB9 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs775396358, COSV99757500; called by mutect2, varscan2
- ABCC1 | c.3767C>T p.T1256I | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100578270; called by muse, mutect2
- ABCC11 | c.4129G>A p.A1377T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100750452, COSV62326325; called by muse, mutect2
- ABCC11 | c.2387A>G p.Y796C | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62324253; called by muse, mutect2
- ABCC2 | c.2624A>G p.H875R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1258429983, COSV100966352; called by muse, mutect2, varscan2
- ABCC3 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV99558553; called by muse, mutect2, varscan2
- ABCC6 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs190761354, COSV52743034; called by muse, mutect2, varscan2
- ABCC8 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV100216454; called by muse, mutect2, varscan2
- ABCD1 | c.1804A>G p.K602E | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as CM110913, COSV99497154; called by muse, mutect2, varscan2
- ABCD3 | c.1751T>C p.L584S | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164558206, COSV100931329; called by muse, mutect2, varscan2
- ABCG2 | c.1253del p.N418Mfs*16 | Frame Shift Del (DEL) | VAF 26/281 reads (9%) | catalogued as COSV52950407; called by mutect2, pindel
- ABHD18 | c.623C>T p.A208V (on ENST00000398965 / NM_001039717.2; = p.A81V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761660121, COSV66294178; called by muse, mutect2, varscan2
- ABR | c.2077G>A p.A693T (on ENST00000302538 / NM_021962.5; = p.A656T on NM_001092.5) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99347329; called by muse, mutect2, varscan2
- AC011455.2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746697410, COSV99671053; called by muse, mutect2, varscan2
- AC090517.4 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 194/710 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772319117, COSV99973933; called by muse, varscan2
- ACADS | c.933+2T>C p.X311_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99656590; called by muse, mutect2, varscan2
- ACBD3 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 934/1366 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs763517769, COSV100830871; called by muse, mutect2, varscan2
- ACBD5 | c.1207T>A p.F403I (on ENST00000375888 / NM_001352568.1; = p.F394I on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV101022448; called by muse, mutect2
- ACOT2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV99468718; called by muse, mutect2
- ACP4 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV54519357; called by muse, mutect2
- ACP7 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747641850, COSV100488395; called by muse, mutect2, varscan2
- ACSBG2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99397117; called by muse, mutect2
- ACSM1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 36/401 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV99532402; called by muse, mutect2
- ACSM2A | c.1415G>A p.R472Q (on ENST00000219054; = p.R393Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs556547446, COSV54590739; called by muse, mutect2, varscan2
- ACSS3 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 38/690 reads (6%) | catalogued as COSV99698144; called by muse, mutect2
- ACTR5 | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.373); catalogued as COSV99709845; called by muse, mutect2
- ADAM33 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773020678, COSV62935537; called by muse, mutect2, varscan2
- ADAM7 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99442792; called by mutect2, varscan2
- ADAMTS12 | c.3718G>A p.V1240I | Missense Mutation (SNP) | VAF 119/592 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100710121; called by muse, mutect2, varscan2
- ADAMTS16 | c.2150G>A p.C717Y | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274205723, COSV99939649; called by muse, mutect2
- ADAR | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs750065985, COSV52715948; called by muse, mutect2
- ADCY10 | c.4790del p.N1597Tfs*4 | Frame Shift Del (DEL) | VAF 58/596 reads (10%) | catalogued as rs753500756; called by pindel, varscan2
- ADCY8 | c.2777A>G p.D926G | Missense Mutation (SNP) | VAF 161/345 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99650296; called by muse, mutect2, varscan2
- ADD2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372010773; called by muse, mutect2, varscan2
- ADGRE5 | c.1873G>A p.A625T (on ENST00000242786 / NM_078481.4; = p.A532T on NM_001784.5) | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99660086; called by muse, mutect2, varscan2
- ADGRF4 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536284658, COSV51956797; called by muse, mutect2, varscan2
- ADGRG4 | c.5615C>G p.S1872C | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV54955683, COSV99794114; called by muse, mutect2, varscan2
- ADGRG4 | c.8396G>C p.W2799S | Missense Mutation (SNP) | VAF 86/850 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99794117; called by muse, mutect2, varscan2
- ADGRL4 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as COSV100875502; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 46/225 reads (20%) | catalogued as rs761350619; called by mutect2, varscan2
- ADORA1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1218495662, COSV58813581; called by muse, mutect2
- AFDN | c.1770A>G p.R590= | Splice Region (SNP) | VAF 30/704 reads (4%) | catalogued as COSV100652315; called by muse, mutect2
- AFDN | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60044122; called by muse, mutect2, varscan2
- AKAP11 | c.519T>A p.D173E | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as COSV99213383; called by muse, mutect2
- AKAP8 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99511653; called by muse, mutect2
- ALG10 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99847868; called by muse, mutect2
- ALK | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 40/549 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV101200890; called by muse, mutect2
- ALMS1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 150/1025 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376632767, COSV52504065; called by muse, mutect2, varscan2
- ALOXE3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs911371858, COSV100502882; called by muse, mutect2
- ALPK2 | c.6246A>G p.Q2082= | Splice Region (SNP) | VAF 10/192 reads (5%) | catalogued as COSV100863990; called by muse, mutect2
- AMBN | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 86/790 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100534233; called by muse, varscan2
- AMPH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768583906, COSV57761502; called by muse, mutect2, varscan2
- ANAPC5 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs115934510, COSV55841788; called by muse, mutect2, varscan2
- ANGPT4 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1205293026, COSV101124607; called by muse, mutect2, varscan2
- ANGPTL2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752232897, COSV99400564; called by muse, mutect2, varscan2
- ANGPTL5 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 66/733 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100527587; called by muse, mutect2
- ANK1 | c.5237G>A p.G1746E | Missense Mutation (SNP) | VAF 22/750 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99223588; called by muse, mutect2
- ANK3 | c.9910C>T p.P3304S | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99777780; called by muse, mutect2, varscan2
- ANKMY2 | c.272-2A>G p.X91_splice | Splice Site (SNP) | VAF 37/656 reads (6%) | catalogued as COSV100186807; called by muse, mutect2
- ANKRD11 | c.3763A>G p.K1255E | Missense Mutation (SNP) | VAF 50/797 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV99968045; called by muse, mutect2
- ANKRD29 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 104/136 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99408973; called by muse, mutect2, varscan2
- ANO2 | c.1004G>A p.R335H (on ENST00000356134 / NM_001278597.3; = p.R339H on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs1486183196, COSV59028580; called by muse, mutect2
- ANO8 | c.2875G>A p.G959R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs776981751, COSV99343954; called by muse, mutect2, varscan2
- AP3D1 | c.3078G>T p.K1026N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV61429990; called by muse, mutect2, varscan2
- AP4M1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373162905; called by muse, varscan2
- APBB2 | c.1928A>G p.K643R (on ENST00000295974 / NM_001166050.2; = p.K644R on NM_004307.2) | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99922293; called by muse, mutect2, varscan2
- APBB2 | c.1016C>T p.T339M (on ENST00000295974 / NM_001166050.2; = p.T340M on NM_004307.2) | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs374925325; called by muse, mutect2, varscan2
- APC | c.4595A>G p.D1532G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs904971132, COSV99964547; ClinVar: uncertain significance; called by muse, mutect2
- APLF | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 91/260 reads (35%) | catalogued as rs773250190, COSV58148815; called by muse, mutect2, varscan2
- APLNR | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200854787, COSV57242011; called by muse, mutect2
- APOL5 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99968317; called by muse, mutect2, varscan2
- APP | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61000615; called by muse, mutect2
- APPL1 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs529656946, COSV99897298; called by muse, mutect2, varscan2
- ARAP2 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 48/624 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs754428866, COSV100393989; called by muse, mutect2
- ARFGAP3 | c.1267A>G p.N423D | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV99605057; called by muse, mutect2, varscan2
- ARHGAP15 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs760147596, COSV54483751; called by muse, varscan2
- ARHGAP27 | c.1182del p.G395Afs*24 (on ENST00000428638 / NM_001282290.1; = p.G54Afs*24 on NM_199282.3) | Frame Shift Del (DEL) | VAF 51/100 reads (51%) | catalogued as rs1567704517; called by mutect2, pindel, varscan2
- ARHGAP35 | c.2014T>C p.S672P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV68332869; called by muse, mutect2, varscan2
- ARHGAP36 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99035104; called by muse, varscan2
- ARHGAP44 | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV52392118, COSV52396304; called by muse, mutect2, varscan2
- ARHGAP44 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99309893; called by muse, mutect2
- ARHGEF1 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100528812; called by muse, mutect2, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 125/196 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2, varscan2
- ARHGEF7 | c.67del p.T23Pfs*13 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs754827718; called by mutect2, pindel
- ARHGEF7 | c.895C>T p.R299W (on ENST00000375741 / NM_001113511.2; = p.R121W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs746611764, COSV99520763; called by muse, mutect2, varscan2
- ARHGEF7 | c.2273G>A p.R758H (on ENST00000375741 / NM_001113511.2; = p.R737H on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.726); catalogued as rs1165161750, COSV99520770; called by muse, mutect2, varscan2
- ARID4A | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530045241, COSV100793936; called by muse, mutect2, varscan2
- ARNT2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs548713623, COSV100308380; called by muse, mutect2, varscan2
- ARRB1 | c.466_468del p.E156del | In Frame Del (DEL) | VAF 34/158 reads (22%) | catalogued as rs759500119; called by pindel, varscan2
- ART5 | c.679del p.H227Mfs*18 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs748137393; called by mutect2, pindel
- ASCC3 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753028569, COSV100225043; called by muse, mutect2, varscan2
- ASH1L | c.7751A>G p.D2584G (on ENST00000368346 / NM_001366177.2; = p.D2579G on NM_018489.3) | Missense Mutation (SNP) | VAF 102/1064 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100853052; called by muse, mutect2
- ASH2L | c.1727T>C p.I576T | Missense Mutation (SNP) | VAF 34/763 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99166909; called by muse, mutect2
- ASPDH | c.224C>T p.A75V (on ENST00000389208 / NM_001114598.2; = p.A20V on NM_001024656.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100975802; called by muse, mutect2, varscan2
- ASPM | c.6074T>C p.V2025A | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99659301; called by muse, mutect2, varscan2
- ASTE1 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV53909192; called by muse, mutect2
- ASTN2 | c.1652G>A p.R551H (on ENST00000313400 / NM_001365069.1; = p.R500H on NM_014010.5) | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs571117828, COSV57788982; called by muse, mutect2
- ATF4 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57479568; called by mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 56/201 reads (28%) | catalogued as rs768611141; called by mutect2, varscan2
- ATF7IP | c.1646-2A>G p.X549_splice | Splice Site (SNP) | VAF 88/464 reads (19%) | catalogued as COSV99661068; called by muse, mutect2, varscan2
- ATG3 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 54/527 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as COSV99343897, COSV99344223; called by muse, mutect2, varscan2
- ATP10D | c.2278G>T p.G760* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99904988; called by muse, mutect2, varscan2
- ATP13A3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as rs746412654, COSV55466509; called by muse, mutect2
- ATP13A4 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 58/644 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs372189734; called by muse, mutect2
- ATP1A1 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99814075; called by muse, mutect2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 55/285 reads (19%) | catalogued as COSV53805755, COSV53811872; called by muse, mutect2, varscan2
- ATP2B1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 160/328 reads (49%) | catalogued as COSV99665093; called by muse, mutect2, varscan2
- ATP6V1A | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769264993, COSV56361556; called by muse, mutect2
- ATP9A | c.1688T>A p.I563N | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100124192; called by muse, mutect2
- ATR | c.5246T>C p.L1749P | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV100637575; called by muse, mutect2, varscan2
- ATRN | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99496414; called by muse, mutect2, varscan2
- AVPI1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs770933514, COSV65697422; called by muse, mutect2, varscan2
- B3GAT1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1449654533, COSV56996714; called by muse, mutect2
- B3GNT7 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as rs746899567, COSV55006857; called by muse, mutect2
- BAAT | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs150178434; called by muse, mutect2, varscan2
- BAD | c.306del p.N103Tfs*15 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as COSV54191195; called by mutect2, varscan2
- BATF3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 57/791 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.914); catalogued as rs1395373528, COSV54658069; called by muse, mutect2
- BCAM | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99538434; called by muse, mutect2
- BCAN | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs759486942, COSV61257438; called by mutect2, varscan2
- BCHE | c.1409T>G p.I470S | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100011933; called by muse, mutect2, varscan2
- BCR | c.2258G>A p.C753Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV100005839; called by muse, mutect2, varscan2
- BEND5 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100884077; called by muse, mutect2
- BEND6 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1047434405, COSV100876728; called by muse, mutect2, varscan2
- BICD1 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs148101509, COSV99861883; called by muse, mutect2, varscan2
- BIRC6 | c.4843G>A p.V1615I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs565438694, COSV101427742; called by muse, mutect2, varscan2
- BIRC6 | c.13148T>C p.L4383P | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101427743; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 42/612 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.916); catalogued as COSV99958486; called by muse, mutect2
- BLNK | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 31/744 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs587702260, COSV99813544; ClinVar: uncertain significance; called by muse, mutect2
- BMP10 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1420667461, COSV99770246; called by muse, mutect2
- BMPER | c.1745+2T>C p.X582_splice | Splice Site (SNP) | VAF 43/287 reads (15%) | catalogued as COSV99778636; called by muse, mutect2, varscan2
- BNC2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 77/963 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV101031800; called by muse, mutect2
- BNIP1 | c.410C>G p.T137S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs969394774, COSV99199357; called by muse, mutect2
- BNIP2 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99985570; called by muse, mutect2, varscan2
- BOD1L1 | c.4223A>G p.D1408G | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99238154; called by muse, mutect2, varscan2
- BOD1L1 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99238157; called by muse, mutect2
- BRINP2 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1168667936, COSV100837790; called by muse, mutect2
- BRIP1 | c.2243A>G p.Y748C | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99368969; called by muse, mutect2
- BRPF1 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs748786588, COSV100121062; called by muse, mutect2, varscan2
- BRSK1 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100510211; called by muse, mutect2, varscan2
- BSND | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100987596; called by muse, mutect2, varscan2
- BTBD11 | c.2454C>T p.G818= (on ENST00000280758 / NM_001018072.2; = p.G355= on NM_001017523.2) | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as rs546906146, COSV99774517; called by muse, mutect2, varscan2
- BTN2A1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV57003066; called by muse, mutect2
- BUB1 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100240760; called by muse, mutect2
- C11orf52 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99585506; called by muse, mutect2
- C11orf80 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV100690653; called by muse, mutect2
- C1QC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.145); catalogued as rs772221556, COSV65889392; called by muse, mutect2, varscan2
- C1QTNF1 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100189681; called by muse, mutect2
- C1QTNF1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189683; called by muse, mutect2, varscan2
- C1S | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 404/790 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV100196307; called by muse, varscan2
- C2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs750860477, COSV54960226; called by muse, mutect2
- C6orf89 | c.332T>G p.I111S (on ENST00000373685; = p.I118S on NM_152734.4) | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100769657; called by muse, mutect2, varscan2
- C8B | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100980674; called by muse, mutect2, varscan2
- C9orf131 | c.1462del p.Q488Rfs*140 | Frame Shift Del (DEL) | VAF 40/465 reads (9%) | catalogued as rs1297698238; called by mutect2, pindel
- C9orf72 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101186473; called by muse, mutect2, varscan2
- CA6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs533616544, COSV66262258, COSV66263535; called by muse, mutect2, varscan2
- CA8 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58771639; called by muse, mutect2
- CACNA1C | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV100214413; called by muse, mutect2, varscan2
- CACNB2 | c.1823G>A p.R608H (on ENST00000324631 / NM_201596.3; = p.R553H on NM_000724.4) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs771011929, COSV56644129; called by muse, mutect2, varscan2
- CACTIN | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50267415; called by muse, mutect2, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by muse, mutect2, varscan2
- CADPS | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99335419; called by muse, mutect2
- CAMK1D | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 102/819 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.279); catalogued as rs201893185, COSV66612603; called by muse, mutect2, varscan2
- CAPRIN2 | c.2351G>A p.S784N | Missense Mutation (SNP) | VAF 37/592 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs377678483; called by muse, mutect2
- CARD11 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62717031; called by muse, mutect2
- CARD6 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99620042; called by muse, mutect2, varscan2
- CASD1 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 14/211 reads (7%) | catalogued as COSV99802156; called by muse, mutect2
- CASP1 | c.1158G>A p.M386I (on ENST00000436863 / NM_033292.4; = p.M365I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99507049; called by muse, varscan2
- CASQ2 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 239/392 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99796922; called by muse, varscan2
- CASS4 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100824499; called by muse, mutect2, varscan2
- CATSPERB | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV99830717; called by muse, mutect2, varscan2
- CBL | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 37/602 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99875326, COSV99876100; called by muse, mutect2
- CBX1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99847954; called by muse, mutect2, varscan2
- CBX8 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 80/97 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99485709; called by muse, mutect2, varscan2
- CCAR1 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 113/273 reads (41%) | catalogued as COSV99770487; called by mutect2, varscan2
- CCDC103 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV53651621; called by muse, mutect2, varscan2
- CCDC136 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); catalogued as rs763885233, COSV52801516; called by muse, mutect2, varscan2
- CCDC150 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 38/602 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs753502575, COSV55879646; called by muse, mutect2
- CCDC186 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 274/943 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100991083, COSV65160616; called by muse, mutect2, varscan2
- CCDC28B | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99356254; called by muse, mutect2, varscan2
- CCDC40 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs779895005, COSV66476198; called by muse, mutect2, varscan2
- CCDC88C | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 95/692 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs757076773, COSV101104686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNA1 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as COSV99714196; called by muse, mutect2
- CCNG1 | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100243495; called by muse, mutect2, varscan2
- CCSER2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56505073, COSV99825345; called by muse, mutect2, varscan2
- CCT6B | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100030388; called by muse, mutect2, varscan2
- CD177 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945765; called by muse, mutect2, varscan2
- CD1B | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV63804572; called by muse, mutect2
- CD28 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.204); catalogued as rs200016310, COSV60730994; called by muse, mutect2, varscan2
- CD2BP2 | c.1007A>C p.D336A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99976887; called by muse, mutect2, varscan2
- CD37 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as rs892651074, COSV100114813; called by muse, mutect2, varscan2
- CD5L | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV63822412; called by muse, mutect2, varscan2
- CD72 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs770655427, COSV99427232; called by muse, mutect2
- CD84 | c.908A>C p.K303T (on ENST00000311224 / NM_001184879.2; = p.K286T on NM_003874.4) | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs200118969, COSV100245769; called by muse, mutect2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 44/364 reads (12%) | catalogued as rs773911500; called by pindel, varscan2
- CDC23 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101203055; called by muse, mutect2, varscan2
- CDC27 | c.182T>A p.L61* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV50437512; called by muse, mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 64/796 reads (8%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2
- CDCA3 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV57529269; called by muse, mutect2, varscan2
- CDH11 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 177/507 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV99216880; called by muse, mutect2, varscan2
- CDH4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs751765138, COSV64646935; called by muse, mutect2, varscan2
- CDHR4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1030618164, COSV100323466; called by muse, mutect2, varscan2
- CDKL4 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 40/558 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.11); catalogued as COSV101115059; called by muse, mutect2
- CDON | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.29); catalogued as COSV99700409; called by muse, mutect2
- CDX2 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as COSV101122641; called by muse, mutect2, varscan2
- CEACAM19 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100715540, COSV62552013; called by muse, mutect2, varscan2
- CENPF | c.8309T>C p.L2770S | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100871432; called by muse, mutect2
- CENPU | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs1050685241, COSV99859703; called by muse, mutect2, varscan2
- CEP135 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 302/1007 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99954031; called by muse, mutect2, varscan2
- CEP70 | c.1588A>G p.R530G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV99388729; called by muse, mutect2, varscan2
- CEP83 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 57/2096 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.073); catalogued as COSV100352585; called by muse, mutect2
- CEP89 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 63/650 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763474593, COSV59862266; called by muse, mutect2
- CES3 | c.1186C>A p.L396I | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV100309767; called by muse, mutect2, varscan2
- CFAP94 | c.2058G>T p.E686D (on ENST00000320267 / NM_001352064.2; = p.E692D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100208777; called by muse, mutect2
- CFH | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 338/504 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs371192606, CM104000; called by muse, mutect2, varscan2
- CH25H | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1380052356, COSV100897325, COSV100897402; called by muse, mutect2
- CHD2 | c.662A>T p.Q221L | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.932); catalogued as COSV100560456; called by muse, mutect2
- CHD4 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV58904577; called by muse, mutect2
- CHD6 | c.5253G>T p.E1751D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV100950479; called by muse, mutect2, varscan2
- CHD6 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV58553993; called by muse, mutect2
- CHIA | c.1351G>A p.V451M (on ENST00000343320; = p.V343M on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as rs545102298, COSV58476452; called by muse, mutect2, varscan2
- CHMP4B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs746089715, COSV54137001; called by muse, mutect2, varscan2
- CHRNA3 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569381256, COSV58774647; called by muse, mutect2, varscan2
- CHRNA7 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1261854197, COSV100180652; called by mutect2, varscan2
- CHRNG | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99285462; called by muse, varscan2
- CIART | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 48/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51744866; called by muse, mutect2
- CIB1 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771152399, COSV100153190, COSV60173166; called by mutect2, varscan2
- CIT | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 81/949 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99948100; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 42/167 reads (25%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP5 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165738671, COSV56366190; called by muse, mutect2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs754415052; called by mutect2, varscan2
- CLASP1 | c.4441C>T p.R1481C | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1273814055, COSV99752412; called by muse, mutect2
- CLEC14A | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV100643460; called by muse, mutect2
- CLEC18C | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.807); catalogued as rs560740555, COSV58500335; called by muse, varscan2
- CLEC4D | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100222853; called by muse, mutect2
- CLINT1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 169/805 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567702393, COSV51626206; called by muse, mutect2, varscan2
- CLIP2 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs782681449, COSV99790860; called by muse, mutect2, varscan2
- CLNS1A | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); catalogued as COSV99627859; called by muse, mutect2
- CLSTN1 | c.1270G>A p.G424R (on ENST00000377298 / NM_001009566.3; = p.G414R on NM_014944.4) | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs369660230; called by muse, mutect2
- CLTC | c.2134T>C p.F712L | Missense Mutation (SNP) | VAF 30/924 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99291550; called by muse, mutect2
- CNDP2 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as COSV100158866; called by muse, mutect2
- CNGA1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs759487836, COSV62053254; ClinVar: uncertain significance; called by muse, mutect2
- CNGA3 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99735915; called by muse, mutect2
- CNKSR1 | c.1456A>G p.T486A (on ENST00000374253 / NM_001297647.2; = p.T479A on NM_006314.3) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV100128163; called by muse, mutect2
- CNTN1 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61646693; called by muse, mutect2, varscan2
- CNTN4 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV101281109; called by muse, mutect2, varscan2
- COL11A2 | c.3925G>A p.G1309R (on ENST00000341947 / NM_080680.3; = p.G1202R on NM_080679.2) | Missense Mutation (SNP) | VAF 112/164 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779569420, COSV59495931; called by muse, mutect2, varscan2
- COL14A1 | c.3978A>C p.K1326N | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99917627; called by muse, mutect2
- COL1A1 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 93/812 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV56806881; called by muse, mutect2, varscan2
- COL4A5 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100086210; called by muse, mutect2, varscan2
- COL4A5 | c.4655T>C p.L1552P | Missense Mutation (SNP) | VAF 81/124 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100086213; called by muse, mutect2, varscan2
- COL4A5 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 280/447 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372369187, COSV60363379; called by muse, mutect2, varscan2
- COL5A1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs774936702, COSV65665617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPG2 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782748032, COSV58406048; called by muse, mutect2
- COX11 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1037345679, COSV100173964; called by muse, mutect2
- CPEB2 | c.1693C>A p.H565N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV99469716; called by muse, mutect2, varscan2
- CPNE3 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52207701; called by muse, mutect2
- CPNE4 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV70190261; called by muse, mutect2
- CPS1 | c.2020A>G p.N674D | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.524); catalogued as COSV99241705; called by muse, mutect2, varscan2
- CRACD | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51721505; called by muse, mutect2
- CREBBP | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV99268247; called by muse, mutect2, varscan2
- CRELD2 | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470164794, COSV100077775; called by muse, mutect2, varscan2
- CRTAM | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99911693; called by muse, mutect2, varscan2
- CRYBG1 | c.3952dup p.S1318Kfs*38 | Frame Shift Ins (INS) | VAF 8/53 reads (15%) | catalogued as rs1271696161; called by mutect2, pindel, varscan2
- CSDE1 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 166/292 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99793876; called by muse, mutect2, varscan2
- CSE1L | c.367T>G p.F123V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521777; called by muse, mutect2
- CSMD3 | c.7676G>A p.G2559D (on ENST00000297405 / NM_001363185.1; = p.G2455D on NM_052900.3) | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158781, COSV99821688; called by muse, mutect2
- CSNK2A2 | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99345119; called by muse, mutect2
- CSPG4 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774099952, COSV57899615; called by muse, varscan2
- CSRNP1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 115/185 reads (62%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759995863, COSV99826653; called by muse, mutect2, varscan2
- CST11 | c.239del p.H80Pfs*6 | Frame Shift Del (DEL) | VAF 31/306 reads (10%) | catalogued as COSV65440931; called by mutect2, pindel, varscan2
- CSTF3 | c.1795+1G>A p.X599_splice | Splice Site (SNP) | VAF 59/714 reads (8%) | catalogued as rs1406366178, COSV60614751; called by muse, mutect2
- CTDSPL | c.415A>G p.T139A (on ENST00000273179 / NM_001008392.2; = p.T128A on NM_005808.3) | Missense Mutation (SNP) | VAF 504/764 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV99828472; called by muse, mutect2, varscan2
- CTNNA2 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV100559678, COSV58136648, COSV58140250; called by muse, mutect2, varscan2
- CTNNB1 | c.482A>T p.N161I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100845949; called by muse, mutect2
- CTSC | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as COSV99910427; called by muse, varscan2
- CTSL | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419953841, COSV58246620; called by muse, mutect2
- CTSS | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs146441878; called by muse, mutect2
- CUL5 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV101263613; called by muse, varscan2
- CUX2 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.978); catalogued as COSV99918352; called by muse, mutect2, varscan2
- CUZD1 | c.1302T>A p.N434K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs370233601; called by muse, mutect2, varscan2
- CXCR1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1008352928, COSV55282387; called by muse, mutect2
- CXCR6 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56118419, COSV99945058; called by muse, mutect2
- CXorf66 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 169/268 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.201); catalogued as COSV100983810; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 80/634 reads (13%) | catalogued as rs775988957; called by mutect2, varscan2
- CYP1A1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs201174966, COSV65697096; called by muse, mutect2, varscan2
- CYRIB | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 33/460 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.411); catalogued as COSV101309581; called by muse, mutect2
- DAPK1 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.196); catalogued as COSV63784504; called by muse, mutect2, varscan2
- DAXX | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs375012684; called by muse, mutect2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBNDD2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100619490; called by muse, varscan2
- DCTN4 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69783127; called by muse, mutect2, varscan2
- DCTPP1 | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100073478; called by muse, mutect2, varscan2
- DDR2 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV100906126; called by muse, mutect2
- DDX1 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99245712; called by muse, mutect2
- DDX24 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.356); catalogued as COSV100427791; called by muse, mutect2, varscan2
- DDX31 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs751295139, COSV99707404; called by muse, mutect2, varscan2
- DDX31 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs370315245; called by muse, mutect2, varscan2
- DDX47 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs199916690; called by muse, mutect2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DEUP1 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1406842387, COSV99976536; called by muse, mutect2
- DGKD | c.2197C>T p.P733S (on ENST00000264057 / NM_152879.3; = p.P689S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99895056; called by muse, mutect2
- DGKZ | c.2900C>T p.T967M (on ENST00000454345 / NM_001105540.2; = p.T779M on NM_003646.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs368913796; called by muse, mutect2
- DHDH | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs368374944; called by muse, mutect2, varscan2
- DHX35 | c.1943A>G p.K648R | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99326285; called by muse, mutect2
- DHX58 | c.1156T>C p.W386R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99287948; called by muse, mutect2, varscan2
- DIP2B | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs1293199990, COSV99997729; ClinVar: uncertain significance; called by muse, mutect2
- DIPK2B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 81/130 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs775096087, COSV65005627; called by muse, mutect2, varscan2
- DIS3L | c.1292A>G p.N431S (on ENST00000319212 / NM_001143688.3; = p.N348S on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100054779, COSV59912471; called by muse, mutect2
- DISP1 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449667; called by muse, mutect2
- DLC1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs148727515, COSV52324792; called by muse, mutect2, varscan2
- DLG2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99712025; called by muse, mutect2, varscan2
- DNAH1 | c.4171T>C p.S1391P | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101324385; called by muse, mutect2, varscan2
- DNAH10 | c.8570G>A p.R2857H (on ENST00000409039; = p.R2796H on NM_207437.3) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs763152052, COSV68994327; called by muse, mutect2, varscan2
- DNAH2 | c.7147G>A p.A2383T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs760670678, COSV66724474; called by mutect2, varscan2
- DNAH3 | c.8671A>G p.M2891V | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1171825689, COSV99764457; called by muse, mutect2
- DNAH7 | c.11156A>T p.D3719V | Missense Mutation (SNP) | VAF 86/986 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768667785, COSV100413488; called by muse, mutect2
- DNAH9 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52368777; called by muse, mutect2
- DNAH9 | c.6526G>A p.V2176I | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs756835987, COSV99303286; called by muse, mutect2, varscan2
- DNAJA4 | c.610C>T p.R204C (on ENST00000343789; = p.R233C on NM_018602.3) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1242423238, COSV100655080, COSV100655203; called by muse, mutect2, varscan2
- DNAJC13 | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as rs1332999039, COSV53453417; called by muse, mutect2, varscan2
- DNAJC16 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101012492; called by muse, mutect2, varscan2
- DNAJC24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV71938535; called by muse, mutect2
- DNMT3B | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV52418076, COSV99140403; called by muse, mutect2
- DOCK2 | c.4283A>G p.D1428G | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99909695; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 48/89 reads (54%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.3848A>T p.Y1283F | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101312803; called by muse, mutect2
- DOCK5 | c.4562C>T p.T1521I | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99375828; called by muse, mutect2
- DOK1 | c.245dup p.E83* | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs750803751; called by mutect2, varscan2
- DOK5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs747068226, COSV99373105; called by muse, mutect2, varscan2
- DPY19L2 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201845477, COSV61045326; called by muse, mutect2, varscan2
- DRC3 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 63/516 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV100572587; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 157/299 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DSG4 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100355138; called by muse, mutect2
- DSP | c.4835T>C p.I1612T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV101131158; called by muse, mutect2, varscan2
- DSP | c.8035G>A p.V2679M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs555167928, COSV100672848; called by muse, mutect2, varscan2
- DST | c.18078G>A p.M6026I (on ENST00000361203 / NM_001374722.1; = p.M3723I on NM_015548.5) | Missense Mutation (SNP) | VAF 46/680 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV99749896; called by muse, mutect2
- DSTYK | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.395); catalogued as COSV100904425; called by muse, mutect2, varscan2
- DTL | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100877127; called by muse, mutect2, varscan2
- DTX1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs370481380; called by mutect2, varscan2
- DUSP15 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 48/579 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99639389; called by muse, mutect2
- DYNC1H1 | c.5774G>A p.R1925Q | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1183114043; called by muse, mutect2, varscan2
- DYNC1H1 | c.10289C>T p.A3430V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV100794233; called by muse, mutect2, varscan2
- DYNC2I2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.491); catalogued as rs773435636, COSV65550707; called by muse, varscan2
- DYRK4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs766865898, COSV50539305; called by muse, mutect2, varscan2
- DYSF | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 104/964 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV99243600; called by muse, mutect2, varscan2
- DYSF | c.3461T>C p.L1154P | Missense Mutation (SNP) | VAF 42/818 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99243605; called by muse, mutect2
- DYTN | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1051826675, COSV71752440; called by muse, mutect2, varscan2
- E2F2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62276541; called by muse, mutect2
- E2F8 | c.68A>T p.K23I | Missense Mutation (SNP) | VAF 21/450 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100001239; called by muse, mutect2
- ECE1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 272/413 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs150644074; called by muse, mutect2, varscan2
- ECM2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 69/680 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs775294587, COSV100755896, COSV60741649; called by muse, mutect2, varscan2
- ECT2L | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV62882814; called by mutect2, varscan2
- EDNRA | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 43/256 reads (17%) | catalogued as COSV100163138; called by muse, mutect2, varscan2
- EEF2 | c.299T>G p.I100S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500529; called by muse, varscan2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 46/143 reads (32%) | catalogued as rs760712775, COSV51135066; called by mutect2, pindel, varscan2
- EFR3A | c.2432A>G p.Y811C | Missense Mutation (SNP) | VAF 35/766 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207120705, COSV99074135; called by muse, mutect2
- EGFLAM | c.2624G>A p.G875D (on ENST00000354891 / NM_001205301.2; = p.G867D on NM_152403.4) | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379616; called by muse, mutect2
- EGR2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99653917; called by muse, mutect2, varscan2
- EHD1 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1487135938, COSV100276784, COSV57737337; called by muse, mutect2, varscan2
- EIF2AK4 | c.3520A>G p.T1174A | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV99773878; called by muse, mutect2
- EIF2B5 | c.820T>C p.Y274H (on ENST00000647909; = p.Y266H on NM_003907.3) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99888954; called by muse, mutect2, varscan2
- EIF3B | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs181409131, COSV100703502; called by muse, mutect2, varscan2
- EIF3L | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs376536658; called by muse, varscan2
- EIF4ENIF1 | c.2471A>G p.H824R | Missense Mutation (SNP) | VAF 146/237 reads (62%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); catalogued as rs1273489678, COSV100348791; called by muse, mutect2, varscan2
- EIF4G2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 396/1049 reads (38%) | catalogued as COSV100379325; called by muse, mutect2, varscan2
- ELAVL2 | c.381A>T p.L127F | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805110; called by muse, mutect2, varscan2
- ELK4 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs755002498, COSV56984572; called by muse, mutect2
- ELL | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99442686; called by muse, mutect2
- ELMOD2 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs373389261; called by muse, mutect2, varscan2
- ELP3 | c.1101-1G>T p.X367_splice | Splice Site (SNP) | VAF 43/564 reads (8%) | catalogued as COSV99833739; called by muse, mutect2
- ENPP2 | c.1991G>A p.S664N (on ENST00000075322 / NM_001040092.3; = p.S716N on NM_006209.5) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99307261; called by muse, mutect2
- EOMES | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99841623; called by muse, mutect2, varscan2
- EP400 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248383112, COSV57773721; called by muse, mutect2, varscan2
- EPG5 | c.3306G>T p.Q1102H | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99956312; called by muse, mutect2
- EPG5 | c.2945A>G p.Y982C | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV99956314; called by muse, mutect2
- EPHA3 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 128/189 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs761576191, COSV60713368; called by muse, mutect2, varscan2
- EPHA4 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV56037259; called by muse, mutect2, varscan2
- EPHA5 | c.1060T>C p.C354R | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99895348; called by muse, mutect2
- EPHA6 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 63/736 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs572811264, COSV101060615, COSV67570244; called by muse, mutect2
- EPHA6 | c.3322C>T p.R1108* | Nonsense Mutation (SNP) | VAF 67/95 reads (71%) | catalogued as rs1394452957, COSV101060616; called by muse, mutect2, varscan2
- EPRS1 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100859270; called by muse, mutect2, varscan2
- EPS15L1 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV50170567; called by muse, mutect2, varscan2
- ERG | c.1123G>A p.A375T (on ENST00000398919 / NM_001243428.1; = p.A351T on NM_004449.4) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733296, COSV99901229; called by muse, mutect2
- ERI2 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184021; called by muse, mutect2, varscan2
- ESCO2 | c.1058T>C p.M353T | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1405136328, COSV100533064; called by muse, mutect2, varscan2
- ESS2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV99350544; called by muse, mutect2
- ESX1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.246); catalogued as COSV65424786; called by muse, mutect2
- EVA1A | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99285231; called by muse, mutect2
- EXTL3 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55038180; called by muse, varscan2
- F13A1 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1000746313, COSV99341912, COSV99342801; called by muse, mutect2
- F2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1423659542, COSV61315682; called by muse, mutect2
- F7 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as CM090299, COSV100660927; called by muse, mutect2
- FAAH | c.893T>G p.L298R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99679838; called by muse, mutect2, varscan2
- FAM120C | c.2227C>A p.L743M | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069488; called by muse, mutect2
- FAM135B | c.3346T>G p.L1116V | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.918); catalogued as COSV52708161; called by muse, mutect2
- FAM151A | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs201727345; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 44/632 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2
- FAM170A | c.311T>C p.L104S | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs377460947; called by muse, mutect2
- FAM181A | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765516099, COSV50889593; called by muse, mutect2, varscan2
- FAM186B | c.662A>C p.D221A | Missense Mutation (SNP) | VAF 44/930 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV99217626; called by muse, mutect2
- FAM200A | c.889T>C p.F297L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV101282695; called by muse, mutect2, varscan2
- FAM24A | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 130/1662 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV100925064; called by muse, mutect2
- FAM47A | c.2255G>A p.G752D | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.481); catalogued as COSV100649668; called by muse, mutect2, varscan2
- FAM83B | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100173920; called by muse, mutect2
- FAM98A | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 33/357 reads (9%) | catalogued as rs1396397106, COSV99478974; called by muse, mutect2
- FAN1 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs372355885; called by muse, mutect2, varscan2
- FASTKD2 | c.1432T>G p.F478V | Missense Mutation (SNP) | VAF 34/725 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52698952; called by muse, mutect2
- FAT1 | c.7866T>A p.D2622E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101498633; called by muse, mutect2, varscan2
- FAT1 | c.7770T>G p.N2590K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101498637; called by muse, mutect2, varscan2
- FAT2 | c.12694A>T p.M4232L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99941392; called by muse, mutect2, varscan2
- FAT2 | c.8546C>T p.A2849V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99941393; called by muse, mutect2, varscan2
- FAT4 | c.10882A>G p.N3628D | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs374041907, COSV58693797; called by muse, mutect2, varscan2
- FAXDC2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100394097; called by mutect2, varscan2
- FBH1 | c.14A>G p.K5R (on ENST00000362091 / NM_178150.3; = p.K56R on NM_032807.4) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100758565; called by muse, mutect2
- FBLN2 | c.2342G>A p.C781Y | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99851215; called by muse, mutect2, varscan2
- FBXO38 | c.2921A>C p.D974A (on ENST00000340253 / NM_205836.3; = p.D899A on NM_030793.5) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99693028; called by muse, mutect2, varscan2
- FBXO44 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52356204; called by muse, mutect2, varscan2
- FBXO48 | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 96/253 reads (38%) | catalogued as COSV100376300; called by muse, mutect2, varscan2
- FCHO1 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99405738; called by muse, mutect2, varscan2
- FCHSD1 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101447489; called by muse, mutect2
- FCSK | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs572464313, COSV55367323; called by muse, mutect2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGD1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs1160132540, COSV100910748, COSV100910903; called by muse, mutect2, varscan2
- FGFR4 | c.1748C>A p.P583Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52805681; called by muse, mutect2, varscan2
- FHOD1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99263745; called by muse, mutect2
- FKBP15 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780183295, COSV52272940; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 40/404 reads (10%) | catalogued as rs752076602; called by mutect2, pindel
- FKBP9 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99638809; called by muse, mutect2
- FKTN | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 60/663 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as rs201590151, COSV99795235; ClinVar: uncertain significance; called by muse, mutect2
- FLNC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as COSV100367524, COSV57965616; called by muse, mutect2, varscan2
- FLRT1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs763041801, COSV99734494; called by muse, varscan2
- FN1 | c.5329G>A p.V1777M | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs369072643; called by muse, mutect2, varscan2
- FNDC3A | c.2038C>T p.Q680* (on ENST00000492622 / NM_001079673.2; = p.Q624* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV101256570; called by muse, mutect2, varscan2
- FNDC8 | c.588T>A p.I196= | Splice Region (SNP) | VAF 8/81 reads (10%) | catalogued as COSV50102148; called by muse, mutect2, varscan2
- FOXH1 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100023414; called by muse, mutect2, varscan2
- FOXL2NB | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs865982825, COSV57728123; called by muse, mutect2
- FRAS1 | c.1887del p.K630Rfs*67 | Frame Shift Del (DEL) | VAF 26/226 reads (12%) | catalogued as rs776570778; called by mutect2, pindel, varscan2
- FRK | c.1348T>C p.Y450H | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101606618; called by muse, mutect2
- FRY | c.8518T>A p.L2840M | Missense Mutation (SNP) | VAF 37/532 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100968732; called by muse, mutect2
- FSCN3 | c.415del p.R139Dfs*8 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as rs750024016, COSV50002110, COSV99133667; called by mutect2, varscan2
- FSTL4 | c.2465C>T p.T822M | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs375184077; called by muse, varscan2
- FYCO1 | c.4339A>G p.I1447V | Missense Mutation (SNP) | VAF 571/942 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV99945055; called by muse, mutect2, varscan2
- FZD8 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020170; called by muse, varscan2
- GABRA3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 896/1461 reads (61%) | catalogued as rs777972856, COSV64794901; called by muse, mutect2, varscan2
- GABRB1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54988801; called by muse, mutect2
- GABRB2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99195601; called by muse, mutect2
- GABRG2 | c.936G>T p.M312I (on ENST00000361925 / NM_001375343.1; = p.M272I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/2525 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.899); catalogued as COSV100729412; called by muse, mutect2
- GADD45GIP1 | c.553_555del p.K185del | In Frame Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs777674072; called by pindel, varscan2
- GALNT11 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV100231551; called by muse, mutect2
- GALNT17 | c.1645T>C p.Y549H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100351831; called by muse, mutect2
- GBP1 | c.1728A>G p.I576M | Missense Mutation (SNP) | VAF 142/1484 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV65083885; called by muse, mutect2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as rs34148688; called by mutect2, pindel, varscan2
- GCDH | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs768925619, CM980873, CM980874, COSV99535643; called by muse, mutect2, varscan2
- GCM1 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99451963; called by muse, mutect2
- GCN1 | c.5953A>G p.I1985V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV100324517; called by muse, mutect2, varscan2
- GEMIN5 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99593520; called by muse, mutect2, varscan2
- GGA2 | c.1796_1798del p.G599del | In Frame Del (DEL) | VAF 102/257 reads (40%) | catalogued as rs749721440; called by mutect2, pindel, varscan2
- GIGYF1 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV99308636; called by muse, mutect2, varscan2
- GIMAP5 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as COSV100500202; called by muse, mutect2, varscan2
- GINS1 | c.305T>A p.L102* | Nonsense Mutation (SNP) | VAF 68/1220 reads (6%) | catalogued as COSV52466132; called by muse, mutect2
- GJA8 | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs145146702, COSV99569009; called by muse, mutect2, varscan2
- GJB3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs369979083, CM149748; ClinVar: likely benign; called by muse, mutect2, varscan2
- GKN1 | c.66+2T>C p.X22_splice | Splice Site (SNP) | VAF 170/1635 reads (10%) | catalogued as rs765025103, COSV65006675; called by muse, mutect2, varscan2
- GLB1L | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs142820300; called by muse, mutect2, varscan2
- GLIPR1L1 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100157231; called by muse, mutect2
- GLP1R | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 48/68 reads (71%) | catalogued as rs141990898; called by muse, mutect2, varscan2
- GLRB | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100029394; called by muse, mutect2
- GNAI1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1211791957, COSV63524154; called by muse, mutect2, varscan2
- GOLGA1 | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 24/545 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV52346999; called by muse, mutect2
- GOT1 | c.253T>G p.S85A | Missense Mutation (SNP) | VAF 78/714 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100981628; called by muse, mutect2, varscan2
- GPATCH8 | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1555619312, COSV100132396; called by muse, mutect2, varscan2
- GPR143 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV66632729; called by muse, mutect2, varscan2
- GPR182 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs142483692; called by muse, mutect2, varscan2
- GPR63 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.226); catalogued as COSV100013083; called by muse, mutect2
- GPR75 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs142326404, COSV100765734; called by muse, mutect2, varscan2
- GPR87 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV99608636; called by muse, mutect2
- GPRASP1 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV100850895; called by muse, mutect2
- GPRC5A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 179/328 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs775011273, COSV50007301; called by muse, mutect2
- GPRIN3 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100310517; called by muse, mutect2
- GREB1 | c.927del p.K311Nfs*65 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs761359837; called by mutect2, pindel, varscan2
- GRID1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199714522; called by muse, mutect2, varscan2
- GRM5 | c.3632C>T p.S1211L (on ENST00000305447 / NM_001143831.2; = p.S1179L on NM_000842.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59612986; called by muse, mutect2
- GRM6 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs111526982, COSV99179420; called by muse, mutect2
- GSTA5 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99489350; called by muse, mutect2
- GTF3C2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 18/304 reads (6%) | catalogued as COSV53125771; called by muse, mutect2
- GUCA1A | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV50004533; called by muse, mutect2, varscan2
- GUCY1A1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56652363; called by muse, mutect2, varscan2
- H1-2 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59189752; called by muse, mutect2
- H2AC1 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 28/614 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV51237681; called by muse, mutect2
- H2BC12 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.067); catalogued as COSV100804551; called by muse, mutect2, varscan2
- H2BC5 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99175191; called by muse, mutect2, varscan2
- H4C5 | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100747847; called by muse, mutect2, varscan2
- HACD4 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs751798439, COSV72136635, COSV72136856; called by muse, mutect2, varscan2
- HAPLN4 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52270254; called by muse, mutect2, varscan2
- HASPIN | c.2078T>C p.L693S | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99560162; called by muse, mutect2, varscan2
- HAUS1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV99958697; called by muse, mutect2
- HAUS5 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV52548497, COSV99178878; called by muse, mutect2
- HCN1 | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV57503237; called by muse, mutect2, varscan2
- HCN3 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100855536; called by muse, mutect2
- HDAC6 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs782183158, COSV100490502; called by muse, mutect2, varscan2
- HDC | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983751; called by muse, mutect2, varscan2
- HEATR1 | c.4735G>A p.A1579T | Missense Mutation (SNP) | VAF 87/676 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs747400321, COSV63982982; called by muse, mutect2, varscan2
- HECTD4 | c.6259G>A p.A2087T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408221012, COSV66393718; called by muse, mutect2, varscan2
- HECTD4 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66394569; called by muse, mutect2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 54/215 reads (25%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HERC4 | c.2362A>G p.T788A (on ENST00000395198 / NM_022079.3; = p.T780A on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV99516414; called by muse, mutect2
- HEXA | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99173653; called by muse, mutect2
- HEY1 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100559140; called by muse, mutect2, varscan2
- HHIP | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1179081644, COSV56838272, COSV56845825; called by muse, mutect2, varscan2
- HIC2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs371166847, COSV68041684; called by muse, mutect2, varscan2
- HIVEP3 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99911188; called by muse, mutect2
- HJURP | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs562372914, COSV100982540; called by muse, mutect2, varscan2
- HK1 | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV100065122; called by muse, mutect2, varscan2
- HLA-DMB | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101186804; called by muse, mutect2
- HLA-E | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1274489578, COSV64927637; called by muse, mutect2
- HNF4A | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57381074, COSV57387821; called by muse, mutect2
- HNRNPDL | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV99786978; called by muse, mutect2
- HNRNPL | c.374T>C p.F125S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99669879; called by muse, mutect2, varscan2
- HOOK1 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100968950; called by muse, mutect2, varscan2
- HOXA7 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636170; called by muse, mutect2
- HPDL | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100587873; called by muse, mutect2
- HPSE2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs767720704, COSV65188152, COSV65188189; called by muse, mutect2, varscan2
- HPSE2 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs770888946, COSV100984688; called by muse, mutect2, varscan2
- HSF5 | c.1148A>G p.H383R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as COSV100089719; called by muse, mutect2, varscan2
- HSP90B1 | c.2400del p.D801Mfs*56 | Frame Shift Del (DEL) | VAF 57/324 reads (18%) | catalogued as COSV55354278; called by mutect2, pindel, varscan2
- HSPA12A | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 142/524 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs782338580, COSV100979699; called by muse, mutect2, varscan2
- HSPA12A | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65023223; called by muse, mutect2
- HSPA1L | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989314; called by muse, mutect2
- HSPG2 | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs781639534, COSV65977032; called by muse, mutect2
- HTT | c.1764C>G p.N588K | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100750285, COSV100750855; called by muse, mutect2, varscan2
- HTT | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 47/666 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1473464204, COSV61865074; called by muse, mutect2
- HYI | c.500A>G p.Q167R (on ENST00000372434 / NM_001330526.2; = p.Q142R on NM_031207.6) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100981164; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 20/172 reads (12%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel
- IFI6 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 62/743 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100191388, COSV59269956; called by muse, mutect2
- IFT122 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99958595; called by muse, mutect2
- IFT140 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101276284; called by muse, mutect2, varscan2
- IFT52 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 48/884 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100887520; called by muse, mutect2
- IFT88 | c.226A>G p.T76A (on ENST00000319980 / NM_001318493.2; = p.T67A on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV100179387; called by muse, mutect2
- IGLON5 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99570417; called by muse, mutect2, varscan2
- IKBKE | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 21/459 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100898056, COSV65624538; called by muse, mutect2
- IL10RB | c.908A>C p.E303A | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV99269731, COSV99270083; called by muse, mutect2, varscan2
- IL17A | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 27/414 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100391376; called by muse, mutect2
- IL17RB | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99860955; called by muse, mutect2, varscan2
- IL24 | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV54320904; called by muse, mutect2
- ILDR1 | c.1573A>G p.K525E (on ENST00000344209 / NM_001199799.2; = p.K481E on NM_175924.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs747580467, COSV56551194, COSV99879185; called by muse, mutect2, varscan2
- IMP4 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759092541, COSV99383579; called by muse, mutect2, varscan2
- INCENP | c.964T>C p.Y322H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV53917399; called by muse, mutect2
- INKA2 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100615727; called by muse, mutect2, varscan2
- INPP4A | c.2558C>T p.T853M (on ENST00000074304 / NM_001134224.1; = p.T814M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1182294597, COSV50866572; called by muse, mutect2
- IPO9 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV64235321; called by muse, mutect2, varscan2
- IPP | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1348365243; called by muse, mutect2
- IQSEC1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56225668; called by muse, mutect2, varscan2
- IRAG1 | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV70211863; called by muse, mutect2, varscan2
- IRF2 | c.150del p.D51Mfs*19 | Frame Shift Del (DEL) | VAF 54/262 reads (21%) | catalogued as COSV101165816; called by pindel, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.2000G>A p.C667Y | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64535855; called by muse, mutect2, varscan2
- ISG20L2 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100493904; called by muse, mutect2, varscan2
- ISL1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs1277059138, COSV100044937; called by muse, mutect2, varscan2
- ITGA7 | c.1190del p.G397Vfs*7 (on ENST00000555728; = p.G353Vfs*7 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs1361836055; called by mutect2, pindel, varscan2
- ITGB1 | c.2132A>G p.N711S | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV56483462; called by muse, mutect2
- ITPRID2 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1243269562, COSV100237771; called by muse, mutect2
- IVL | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.608); catalogued as COSV100908081; called by muse, mutect2
- JAG1 | c.1594A>T p.N532Y | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99652335; called by muse, mutect2, varscan2
- JAK3 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101512865; called by muse, mutect2
- JPH4 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58116391; called by muse, mutect2
- JUN | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64664399; called by muse, mutect2, varscan2
- KAT14 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100890016; called by muse, mutect2
- KAT6B | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.124); catalogued as COSV99767166; called by muse, mutect2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KBTBD4 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV99772200; called by muse, mutect2, varscan2
- KBTBD7 | c.1775A>G p.E592G | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101067999; called by muse, mutect2
- KCNA1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV66838566; called by muse, mutect2
- KCNA1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66836546; called by muse, mutect2
- KCNAB1 | c.701C>T p.A234V (on ENST00000490337 / NM_172160.3; = p.A223V on NM_003471.3) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs1246455398, COSV56748392; called by muse, mutect2, varscan2
- KCNC3 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338146006, COSV100979144; called by muse, mutect2, varscan2
- KCNG4 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369257369, COSV100376853; called by muse, mutect2, varscan2
- KCNK17 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 102/153 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs191023425, COSV64678206; called by muse, mutect2, varscan2
- KCTD8 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV63586871, COSV63595338; called by muse, mutect2
- KDM1B | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 256/538 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs921225400, COSV99923791; called by muse, mutect2, varscan2
- KDM2A | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100445348; called by muse, mutect2, varscan2
- KDM4A | c.429G>A p.K143= | Splice Region (SNP) | VAF 39/259 reads (15%) | catalogued as COSV100969343; called by muse, mutect2, varscan2
- KDM4D | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs782522479, COSV100624097; called by muse, mutect2, varscan2
- KDM6A | c.1846A>T p.T616S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as CD146938, COSV100937838; called by muse, mutect2
- KIAA1109 | c.12626A>T p.K4209I | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99145435; called by muse, mutect2, varscan2
- KIAA1109 | c.13075T>A p.S4359T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV99145436; called by muse, mutect2, varscan2
- KIAA1328 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs762601395, COSV99692969; called by muse, mutect2
- KIDINS220 | c.3513T>A p.D1171E | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs776390582, COSV99874763; called by muse, mutect2, varscan2
- KIF1A | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs767331601, COSV57494430; called by muse, mutect2, varscan2
- KIF1B | c.1589del p.K530Rfs*13 (on ENST00000377086 / NM_001365952.1; = p.K484Rfs*13 on NM_015074.3) | Frame Shift Del (DEL) | VAF 68/507 reads (13%) | catalogued as rs34768638; called by mutect2, pindel, varscan2
- KIF23 | c.1463T>A p.I488N | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV99531748; called by muse, mutect2
- KIF3A | c.1705A>G p.R569G | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV66415334; called by muse, mutect2
- KIF4B | c.2398T>C p.F800L | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV70530164; called by muse, mutect2, varscan2
- KIN | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs543372718, COSV101092389; called by muse, mutect2
- KIRREL3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 171/676 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746070014, COSV73107063; called by muse, mutect2, varscan2
- KL | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745808758, COSV101198958; called by muse, mutect2, varscan2
- KLF12 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); catalogued as rs1223921454, COSV100888383; called by muse, mutect2
- KLHL1 | c.423del p.L143Wfs*32 | Frame Shift Del (DEL) | VAF 215/474 reads (45%) | catalogued as COSV64784549; called by mutect2, pindel, varscan2
- KLHL42 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV67146013; called by muse, mutect2, varscan2
- KLK15 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1383374843, COSV100032419; called by muse, mutect2
- KLRB1 | c.259+1G>A p.X87_splice | Splice Site (SNP) | VAF 76/1110 reads (7%) | catalogued as COSV57590537, COSV99987144; called by muse, mutect2
- KMT2A | c.1636T>A p.L546I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100627682; called by muse, mutect2
- KMT2A | c.9454G>A p.G3152R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63283915; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2C | c.4880A>G p.D1627G | Missense Mutation (SNP) | VAF 48/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100065018; called by muse, mutect2
- KMT2C | c.1445T>C p.M482T | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs962605833, COSV100065022; called by muse, mutect2
- KMT2D | c.13570C>T p.R4524W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778634045, COSV56457421; called by muse, mutect2, varscan2
- KRI1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as rs777874500, COSV100469627; called by muse, mutect2, varscan2
- KRT1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99358431; called by muse, mutect2
- KRT17 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs368091501, COSV60860308; called by mutect2, varscan2
- LAMB1 | c.1559A>G p.N520S | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV99739625; called by muse, mutect2, varscan2
- LAMB3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as rs1330867759, COSV100620035; called by muse, mutect2, varscan2
- LAMB3 | c.946T>C p.C316R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620037; called by muse, mutect2, varscan2
- LARP4B | c.1929+2T>C p.X643_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100294966; called by muse, mutect2, varscan2
- LCP2 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV50454182; called by muse, mutect2, varscan2
- LEF1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as rs146861754; called by muse, mutect2, varscan2
- LETM1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1465591490, COSV100245116; called by muse, mutect2, varscan2
- LGALS13 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs370450997; called by muse, mutect2
- LGALS4 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100313055; called by muse, mutect2
- LGALS8 | c.465+2T>C p.X155_splice | Splice Site (SNP) | VAF 22/392 reads (6%) | catalogued as COSV99436180; called by muse, mutect2
- LIG3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52005519; called by muse, varscan2
- LIG3 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as rs567712080, COSV52010676; called by muse, varscan2
- LILRA1 | c.1376T>C p.V459A | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV52182167; called by muse, mutect2
- LIMA1 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100372158; called by muse, mutect2, varscan2
- LIMK1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 227/1077 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs375588485; called by muse, mutect2, varscan2
- LIPC | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100134086; called by muse, mutect2, varscan2
- LIPG | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.167); catalogued as COSV99724226; called by muse, mutect2, varscan2
- LMBRD2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs938938053, COSV99682507; called by muse, mutect2
- LMNTD1 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 55/633 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99279226; called by muse, mutect2
- LNX2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs1251500616, COSV60335580; called by muse, mutect2, varscan2
- LONP2 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754630302, COSV53522904; called by muse, varscan2
- LOXL2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV66692208; called by muse, mutect2, varscan2
- LOXL3 | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV99239384; called by muse, mutect2, varscan2
- LPAR3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); catalogued as rs544005031, COSV101004652; called by muse, mutect2, varscan2
- LRP5 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774342727, CM143633, COSV53713684; called by muse, mutect2, varscan2
- LRP6 | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99742131; called by muse, mutect2
- LRRC10 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs373847240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC39 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 434/652 reads (67%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV100734299; called by muse, mutect2, varscan2
- LRRFIP2 | c.1700-2A>C p.X567_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100368087; called by muse, mutect2, varscan2
- LRRIQ1 | c.2944A>G p.I982V | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.556); catalogued as COSV101279269; called by muse, mutect2
- LRRIQ3 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 317/554 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs534493116, COSV100598687, COSV63044305; called by muse, mutect2, varscan2
- LRRK2 | c.3001A>G p.S1001G | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV54159305; called by muse, mutect2, varscan2
- LRSAM1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140467743; called by muse, mutect2
- LRTM1 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99835822; called by muse, mutect2, varscan2
- LSM14B | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314159584, COSV99443665; called by muse, mutect2
- LTV1 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV100849529; called by muse, mutect2
- LUC7L3 | c.1165del p.S389Vfs*3 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | catalogued as rs1229438198; called by mutect2, pindel, varscan2
- LYPLA1 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57605645; called by muse, mutect2
- MACF1 | c.21239C>T p.T7080I (on ENST00000372915; = p.T5125I on NM_012090.5) | Missense Mutation (SNP) | VAF 180/282 reads (64%) | catalogued as COSV99240584; called by muse, mutect2, varscan2
- MAEL | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100774749; called by muse, mutect2, varscan2
- MAGEB1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV66775656; called by muse, mutect2
- MAP1B | c.3379T>A p.S1127T | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.321); catalogued as rs1376461532, COSV99701636; called by muse, mutect2
- MAP3K12 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs1007891185, COSV57233100; called by muse, mutect2, varscan2
- MAP3K13 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs765143232, COSV53985938; called by muse, mutect2, varscan2
- MAP3K14 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408097016, COSV100766364, COSV100766571; called by muse, mutect2, varscan2
- MAP3K4 | c.4064G>T p.G1355V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814967; called by muse, mutect2
- MAP3K6 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as rs759155929, COSV99585139; called by muse, mutect2, varscan2
- MAP4K5 | c.2212A>G p.T738A | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs971519838, COSV50162497; called by muse, mutect2
- MAP6 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100496375; called by muse, mutect2, varscan2
- MARCHF6 | c.2567T>A p.V856D | Missense Mutation (SNP) | VAF 250/1105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99929262; called by muse, mutect2, varscan2
- MAST4 | c.5637del p.S1880Afs*59 (on ENST00000403625 / NM_001164664.2; = p.S1691Afs*59 on NM_015183.3) | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as COSV99843467, COSV99845332; called by mutect2, varscan2
- MAST4 | c.6108G>T p.W2036C (on ENST00000403625 / NM_001164664.2; = p.W1847C on NM_015183.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV55116785, COSV99842501; called by muse, mutect2
- MBD2 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 390/503 reads (78%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs780879642, COSV99839794; called by muse, mutect2, varscan2
- MCC | c.458-2A>C p.X153_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100201926; called by muse, mutect2
- MCTP2 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 47/1726 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161520000, COSV100537145; called by muse, mutect2
- MDC1 | c.5719C>T p.R1907W | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768568532, COSV64525257; called by muse, mutect2, varscan2
- MDGA2 | c.1562C>A p.P521Q (on ENST00000399232 / NM_001113498.2; = p.P223Q on NM_182830.4) | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.166); catalogued as rs866325480, COSV62100215; called by muse, mutect2, varscan2
- ME1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100866287; called by muse, mutect2, varscan2
- MED1 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 26/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100327266; called by muse, mutect2
- MED12 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs759857680, COSV61341687; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- MED13L | c.4113C>T p.Y1371= | Splice Region (SNP) | VAF 137/276 reads (50%) | catalogued as rs767543191, COSV99927586; called by muse, varscan2
- MED23 | c.3648G>A p.W1216* | Nonsense Mutation (SNP) | VAF 6/107 reads (6%) | catalogued as COSV100644678; called by muse, mutect2
- MED24 | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672901; called by muse, mutect2, varscan2
- MELTF | c.204G>A p.A68= | Splice Region (SNP) | VAF 10/14 reads (71%) | catalogued as rs763657040, COSV99585727; called by muse, varscan2
- METAP2 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 36/1212 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99704589; called by muse, mutect2
- METTL23 | c.55_57del p.R19del | In Frame Del (DEL) | VAF 80/119 reads (67%) | catalogued as rs1568010466; called by pindel, varscan2
- METTL6 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1370772155, COSV101084959; called by muse, mutect2
- MFN2 | c.306del p.F102Lfs*11 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs777012596; called by mutect2, pindel, varscan2
- MFN2 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99336406; called by muse, mutect2
- MFSD6L | c.309T>A p.N103K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV100266012; called by muse, mutect2
- MGA | c.4399C>T p.R1467C | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs769019565, COSV99578151; called by muse, mutect2, varscan2
- MGAT3 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.134); catalogued as COSV100361673; called by muse, mutect2, varscan2
- MITF | c.487C>T p.P163S (on ENST00000448226 / NM_006722.3; = p.P57S on NM_000248.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV100096380; called by muse, mutect2
- MKI67 | c.5734G>T p.G1912C | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100896043; called by muse, mutect2
- MKRN1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV55436087; called by muse, mutect2, varscan2
- MLLT1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53130687, COSV53133326; called by muse, mutect2
- MMP2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777819097, COSV54600313; called by muse, mutect2, varscan2
- MMP27 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs766084332, COSV52780235; called by muse, varscan2
- MMP7 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.957); catalogued as rs751581884, COSV52771701, COSV99497099; called by muse, mutect2, varscan2
- MOCS3 | c.1334dup p.L446Pfs*18 | Frame Shift Ins (INS) | VAF 41/214 reads (19%) | catalogued as rs775328079; called by mutect2, pindel, varscan2
- MON1B | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867170901, COSV99941443; called by muse, mutect2
- MORC2 | c.266A>G p.K89R (on ENST00000397641 / NM_001303256.3; = p.K27R on NM_014941.3) | Missense Mutation (SNP) | VAF 203/396 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53196285, COSV99309352; called by muse, mutect2, varscan2
- MPRIP | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs944814693, COSV100505198; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- MROH1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1284426599, COSV100395476; called by muse, mutect2
- MRPL1 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV100213701; called by muse, mutect2
- MRPL18 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100364633; called by muse, mutect2, varscan2
- MRPL18 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 112/210 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV99277083; called by muse, varscan2
- MRPL44 | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.501); catalogued as COSV51313506; called by muse, mutect2, varscan2
- MSL2 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100017145; called by muse, mutect2, varscan2
- MTMR3 | c.3131C>T p.T1044I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100070345; called by muse, mutect2, varscan2
- MTMR6 | c.1659G>T p.L553F | Missense Mutation (SNP) | VAF 94/1501 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.133); catalogued as COSV101110694; called by muse, mutect2
- MTMR6 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101110695; called by muse, mutect2, varscan2
- MTNR1B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as rs754089451, COSV57069050; called by muse, mutect2
- MTTP | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.018); catalogued as COSV99644654; called by muse, varscan2
- MUC16 | c.10454C>T p.A3485V | Missense Mutation (SNP) | VAF 62/621 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs200594255, COSV101202141, COSV67476944; called by muse, mutect2, varscan2
- MUC17 | c.8605A>G p.T2869A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100071270; called by muse, mutect2
- MUC4 | c.2213T>G p.L738R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as COSV100638798; called by muse, mutect2, varscan2
- MYBL2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV99405916; called by muse, mutect2
- MYBPH | c.986A>T p.D329V | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99704308; called by muse, mutect2
- MYBPH | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs749355783, COSV55142306; called by muse, mutect2, varscan2
- MYCBP2 | c.4375T>C p.C1459R (on ENST00000357337; = p.C1497R on NM_015057.5) | Missense Mutation (SNP) | VAF 47/832 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs886196673, COSV62026894; called by muse, mutect2
- MYCN | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324334894, COSV99807954; called by muse, mutect2, varscan2
- MYH10 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.358); catalogued as rs77768450; called by muse, mutect2, varscan2
- MYH13 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1331637610, COSV52830270; called by muse, mutect2, varscan2
- MYL6B | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs779611293, COSV99255049; called by muse, mutect2, varscan2
- MYLK | c.472del p.E158Sfs*79 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | catalogued as rs770373926; called by mutect2, pindel, varscan2
- MYLK2 | c.1424+1G>A p.X475_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | catalogued as COSV65659902; called by muse, mutect2
- MYO15A | c.5826-1G>T p.X1942_splice | Splice Site (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99230742; called by muse, mutect2, varscan2
- MYO16 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 49/844 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV51780987; called by muse, mutect2
- MYO1A | c.1270-2A>C p.X424_splice | Splice Site (SNP) | VAF 17/137 reads (12%) | catalogued as COSV100270455; called by muse, mutect2, varscan2
- MYO1D | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 126/728 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs773457917, COSV59017779; called by muse, mutect2, varscan2
- MYO3B | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 36/730 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100508971, COSV100509905; called by muse, mutect2
- MYO5C | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99953913; called by muse, mutect2
- MYO7A | c.5540G>A p.S1847N | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101289011; called by muse, mutect2, varscan2
- MYOM2 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV100036425; called by muse, mutect2
- NAALAD2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100427937; called by muse, mutect2
1,309 further variants in this file (799 protein-altering or splice-affecting, 466 silent, 44 other) are not listed here.
